Somatic mutation profile of tumor specimen TCGA-20-1685-01A (aliquot TCGA-20-1685-01A-01W-0633-09) from TCGA case TCGA-20-1685, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.8 years (16,745 days).
Specimen TCGA-20-1685-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a778e67-9737-46b6-8a97-3cc4e5c32e87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-1685-10A (Blood Derived Normal), aliquot TCGA-20-1685-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c38b3a9b-0e2d-4dc0-b658-ab225648107f

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Nonsense Mutation 4, In Frame Del 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 55/76 reads (72%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB11 | c.1334T>A p.I445N | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99791793; called by muse, mutect2
- ABCB5 | c.2833C>G p.Q945E (on ENST00000404938 / NM_001163941.2; = p.Q500E on NM_178559.6) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0.02); catalogued as rs1433799150, COSV51702560, COSV51711985; called by muse, mutect2, varscan2
- AC090517.4 | c.1447C>G p.Q483E | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.599); catalogued as COSV50997760, COSV99974311; called by muse, mutect2, varscan2
- ARG2 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 63/87 reads (72%) | catalogued as COSV53619946; called by muse, mutect2, varscan2
- ARHGAP33 | c.2506G>C p.A836P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV50126577; called by muse, mutect2
- ARL5B | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV66011325; called by muse, mutect2, varscan2
- ATP11C | c.1561G>T p.G521* | Nonsense Mutation (SNP) | VAF 48/252 reads (19%) | catalogued as COSV59566440; called by muse, mutect2, varscan2
- C2CD3 | c.4829C>A p.T1610N | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV58094220; called by muse, mutect2, varscan2
- CFHR5 | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.103); catalogued as COSV56823000; called by muse, mutect2, varscan2
- CNGA1 | c.1369C>A p.L457I | Missense Mutation (SNP) | VAF 78/397 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV62054740; called by muse, mutect2, varscan2
- CNOT11 | c.744C>G p.D248E | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV56820179; called by muse, mutect2, varscan2
- CUBN | c.10188C>A p.N3396K | Missense Mutation (SNP) | VAF 101/275 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV64718363; called by muse, mutect2, varscan2
- DST | c.12784G>C p.E4262Q (on ENST00000361203 / NM_001374722.1; = p.E1850Q on NM_015548.5) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV55020810; called by muse, mutect2, varscan2
- EEA1 | c.1505C>G p.A502G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as COSV59286623; called by muse, mutect2, varscan2
- ESF1 | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV52521693; called by muse, mutect2, varscan2
- ETNK2 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as rs533254441, COSV65819914; called by muse, mutect2, varscan2
- FGB | c.836G>T p.W279L | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57418713; called by muse, mutect2, varscan2
- GRIK4 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs562688896, COSV70803233; called by muse, mutect2, varscan2
- H3-5 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.423); catalogued as COSV61186850, COSV61188339; called by muse, mutect2, varscan2
- IGF2R | c.2855G>T p.S952I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100807120; called by muse, mutect2
- IGHMBP2 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54823268; called by muse, mutect2, varscan2
- KRT83 | c.665G>C p.C222S | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV53340737; called by muse, mutect2, varscan2
- LRRC43 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1266655197, COSV60290567; called by muse, mutect2, varscan2
- LTF | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV99207373; called by muse, mutect2, varscan2
- MAN2A2 | c.3449G>T p.G1150V | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs1185285821, COSV64638620; called by muse, mutect2, varscan2
- NPAP1 | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV61505154, COSV61508037; called by muse, mutect2, varscan2
- NUDCD2 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs190479135, COSV57084907; called by muse, mutect2, varscan2
- NUP188 | c.5163G>C p.K1721N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as COSV65331147; called by muse, mutect2, varscan2
- NXPE4 | c.1114G>A p.D372N (on ENST00000375478 / NM_001077639.2; = p.D88N on NM_017678.3) | Missense Mutation (SNP) | VAF 175/415 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as COSV100970341; called by muse, mutect2, varscan2
- PDZD8 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV57826243; called by muse, mutect2, varscan2
- PHC2 | c.839A>G p.K280R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV57107427; called by muse, mutect2
- PHIP | c.2312T>C p.V771A | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1250347078, COSV51505797; called by muse, mutect2, varscan2
- PRKACB | c.696G>C p.M232I | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV65759856; called by muse, mutect2, varscan2
- PRUNE2 | c.7193T>G p.L2398W | Missense Mutation (SNP) | VAF 93/117 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65042734; called by muse, mutect2, varscan2
- RAD51AP2 | c.3365C>T p.P1122L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67588259; called by muse, mutect2, varscan2
- RGS21 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV69882751; called by muse, mutect2, varscan2
- SLC2A9 | c.573G>C p.E191D | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs376990050; called by muse, mutect2, varscan2
- SLC9A6 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs1556618502, COSV65788203; called by muse, mutect2, varscan2
- SMARCA2 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.745); catalogued as COSV61808723; called by muse, mutect2, varscan2
- STK33 | c.967T>A p.F323I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59403154; called by muse, mutect2, varscan2
- TBPL2 | c.357C>A p.H119Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.044); catalogued as rs369692725, COSV55972786; called by muse, mutect2, varscan2
- TRMT9B | c.1225A>T p.M409L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.056); catalogued as COSV101501540; called by muse, mutect2, varscan2
- TTF2 | c.2080A>T p.T694S | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65632848; called by muse, mutect2, varscan2
- UNC13C | c.171C>A p.Y57* | Nonsense Mutation (SNP) | VAF 53/289 reads (18%) | catalogued as COSV52884838; called by muse, mutect2, varscan2
- UNC79 | c.5737A>T p.R1913W (on ENST00000393151 / NM_001346218.2; = p.R1736W on NM_020818.5) | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99826625; called by muse, mutect2
- USPL1 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 82/113 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55000390; called by muse, mutect2, varscan2
- ZNF23 | c.1090T>A p.Y364N | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV100612094, COSV100612299; called by muse, mutect2
- FZD3 | c.1334dup p.Y445* | Nonsense Mutation (INS) | VAF 77/256 reads (30%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.699_707del p.V234_T236del | In Frame Del (DEL) | VAF 70/198 reads (35%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.843_851del p.F282_E284del | In Frame Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- LAMC2 | c.405-11_444delinsCCCAGAGACTCCAAGTGTGACTGTGA p.X135_splice | Splice Site (DEL) | VAF 7/63 reads (11%) | called by pindel, varscan2*
- ARHGEF12 | c.3333A>G p.E1111= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as rs767836054, COSV63105413; called by muse, mutect2, varscan2
- CELSR2 | c.2385G>A p.K795= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV54773797; called by muse, mutect2, varscan2
- GALNT13 | c.666G>A p.L222= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV67224625, COSV67238192; called by muse, mutect2, varscan2
- GLB1L2 | c.1444A>C p.R482= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV60279064; called by muse, mutect2, varscan2
- HERC2 | c.10173G>T p.L3391= | Silent (SNP) | VAF 65/140 reads (46%) | catalogued as COSV55328540; called by muse, mutect2, varscan2
- INPPL1 | c.186T>C p.Y62= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53356448; called by muse, mutect2, varscan2
- KRTAP13-4 | c.447A>G p.P149= | Silent (SNP) | VAF 89/116 reads (77%) | catalogued as COSV61879447; called by muse, mutect2, varscan2
- NAA16 | c.885A>G p.R295= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs749641808, COSV65065452; called by muse, mutect2, varscan2
- PCDHB15 | c.663C>G p.P221= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV50858568, COSV50860015, COSV50977209; called by muse, mutect2
- PGLYRP4 | c.1059A>G p.R353= | Silent (SNP) | VAF 121/280 reads (43%) | catalogued as COSV62835482; called by muse, mutect2, varscan2
- PKP4 | c.2271G>C p.V757= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV61579020; called by muse, varscan2
- SARS1 | c.252G>A p.V84= | Silent (SNP) | VAF 37/251 reads (15%) | catalogued as COSV52321358; called by muse, mutect2, varscan2
- SENP7 | c.1102C>T p.L368= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV58613248; called by muse, mutect2, varscan2
- SSH3 | c.432G>A p.T144= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs528844729, COSV57385129; called by muse, mutect2, varscan2
- TMEM132B | c.2259A>G p.E753= | Silent (SNP) | VAF 44/217 reads (20%) | catalogued as rs769774909, COSV54756755; called by muse, mutect2, varscan2
- TSFM | c.981G>A p.S327= (on ENST00000323833 / NM_001172696.2; = p.S306= on NM_005726.6) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs149429981; called by muse, mutect2, varscan2
- DEPDC5 | c.1870+3502T>G | Intron (SNP) | VAF 26/60 reads (43%) | catalogued as COSV56700385; called by muse, mutect2, varscan2
- GFOD1 | c.253+16423C>G | Intron (SNP) | VAF 10/48 reads (21%) | catalogued as COSV64953234; called by muse, mutect2, varscan2
